TCGA case TCGA-AG-3891 — Rectum Adenocarcinoma (TCGA-READ)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Rectum; Tissue source site: Indivumed. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/d461e83a-7f09-4e4c-ac49-f05766a6051a

Demographics
Sex at birth: female; Country of residence at enrollment: Germany; Age at index: 66 years; Vital status: Alive.

Diagnoses (1)
1. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; ICD-10 code: C20; Tissue or organ of origin: Rectum, NOS; Site of resection or biopsy: Rectum, NOS; Classification of tumor: primary; Age at diagnosis: 66.8 years (24,411 days); Year of diagnosis: 2009; AJCC staging edition: 6th; AJCC pathologic T: T2; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage I; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Days to last follow up: 548 days (1.5 years).
   Pathology details: Lymph nodes positive: 0; Lymph nodes tested: 13; Lymphatic invasion present: Yes.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation Therapy, NOS.

Follow-up (2 entries)
- Days to follow up: 30 days; Disease response: With Tumor.
- Days to follow up: 548 days (1.5 years); Disease response: Tumor Free.

Other clinical attributes
- Timepoint category: Prior to Diagnosis; Comorbidities: Colon Polyps; Risk factors: Colon Polyps.

Family history
- Relative with cancer history: no.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-AG-3891-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Longest dimension: 0.9; Intermediate dimension: 0.6; Shortest dimension: 0.4.
  Slide TCGA-AG-3891-01A-01-TS1: Section location: Top; Percent tumor cells: 70; Percent tumor nuclei: 75; Percent normal cells: 8; Percent necrosis: 10; Percent stromal cells: 12.
  Slide TCGA-AG-3891-01A-01-BS1: Section location: Bottom; Percent tumor cells: 55; Percent tumor nuclei: 65; Percent normal cells: 20; Percent necrosis: 5; Percent stromal cells: 20.
- Sample TCGA-AG-3891-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-AG-3891-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Rectal Adenocarcinoma; History neoadjuvant treatment: No; Prospective collection: No; Retrospective collection: Yes; Tumor status: With tumor; Lymph nodes examined: Yes; Lymphovascular invasion indicator: Yes; KRAS gene analysis indicator: No; BRAF gene analysis indicator: No; History colon polyps: Yes; Mismatch rep proteins tested by IHC: No.
- Follow-up form: Lost to follow-up: No; Treatment outcome at TCGA followup: Complete Remission/Response; Tumor status: Tumor free; New tumor event diagnosis indicator: No.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 548 days; disease-specific survival: no event (censored), 548 days; progression-free interval: no event (censored), 548 days.
